Somatic mutation profile of cancer-model specimen HCM-CSHL-0868-C56-85A (3D Organoid, passage 11; aliquot HCM-CSHL-0868-C56-85A-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0868-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIB; FIGO stage: Stage IIIB; Tumor grade: High Grade; Age at diagnosis: 62.3 years (22,759 days).
Specimen HCM-CSHL-0868-C56-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64408928-ad2f-4ffb-94ad-dbd2b7394468.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0868-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0868-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24996e18-3949-4966-b1b0-192c99e6a406

The open-access MAF lists 79 somatic variants for this specimen: 58 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 19, Nonsense Mutation 3, Translation Start Site 2, 5'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 181/182 reads (99%) | catalogued as rs786201592, COSV52735606, COSV52751148, COSV52783951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP2C2 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 187/187 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753015843, COSV52292404; called by muse, mutect2, varscan2
- CSNK1G3 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1377658128; called by muse, mutect2, varscan2
- F5 | c.612G>C p.Q204H | Missense Mutation (SNP) | VAF 199/425 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63122659; called by muse, mutect2, varscan2
- GANAB | c.1790C>A p.P597H | Missense Mutation (SNP) | VAF 132/579 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60464958; called by mutect2, varscan2
- GMPPB | c.1061C>T p.P354L (on ENST00000308388 / NM_021971.4; = p.P381L on NM_013334.3) | Missense Mutation (SNP) | VAF 235/236 reads (100%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs913881676; called by muse, mutect2, varscan2
- IMMT | c.1895G>C p.R632T | Missense Mutation (SNP) | VAF 38/490 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1381448415; called by muse, mutect2
- IQCB1 | c.1367T>C p.V456A | Missense Mutation (SNP) | VAF 133/449 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs1456257526; called by muse, mutect2, varscan2
- NCBP2AS2 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 268/1093 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs267599756; called by muse, mutect2, varscan2
- NPAS3 | c.2311G>T p.G771C (on ENST00000356141 / NM_001164749.2; = p.G739C on NM_022123.3) | Missense Mutation (SNP) | VAF 99/250 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as rs998070414; called by muse, mutect2, varscan2
- OR5BS1P | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 210/352 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs547782447; called by muse, mutect2, varscan2
- RTKN | c.469G>A p.E157K (on ENST00000272430 / NM_001015055.2; = p.E144K on NM_033046.2) | Missense Mutation (SNP) | VAF 212/342 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV99269864; called by muse, mutect2, varscan2
- SIL1 | c.708C>G p.N236K | Missense Mutation (SNP) | VAF 272/623 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1204909499; called by muse, mutect2, varscan2
- SLC27A3 | c.1177G>T p.V393L (on ENST00000271857; = p.V265L on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 526/1006 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV55165041; called by muse, mutect2, varscan2
- SLCO2B1 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 564/866 reads (65%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs752102813; called by muse, mutect2, varscan2
- SSBP3 | c.526G>A p.G176R (on ENST00000371320 / NM_145716.4; = p.G156R on NM_018070.5) | Missense Mutation (SNP) | VAF 235/488 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100486455; called by muse, mutect2, varscan2
- TNK2 | c.2851G>A p.D951N | Missense Mutation (SNP) | VAF 889/1170 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as rs764262169, COSV57373752; called by muse, mutect2, varscan2
- ZNF408 | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 244/244 reads (100%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.292); catalogued as rs940672700; called by muse, mutect2, varscan2
- ABCC6 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 104/480 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, varscan2
- ACADM | c.61A>G p.R21G | Missense Mutation (SNP) | VAF 122/288 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ACY3 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 347/768 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- AFMID | c.565G>C p.G189R | Missense Mutation (SNP) | VAF 374/377 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BCL2L12 | c.220A>G p.R74G | Missense Mutation (SNP) | VAF 107/369 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL11A1 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 16/316 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2
- CTTNBP2 | c.901G>T p.V301L | Missense Mutation (SNP) | VAF 234/385 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH10 | c.8768A>T p.D2923V (on ENST00000409039; = p.D2862V on NM_207437.3) | Missense Mutation (SNP) | VAF 162/531 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DYNC2H1 | c.8123T>C p.V2708A | Missense Mutation (SNP) | VAF 15/406 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.649); called by muse, mutect2
- FAM50B | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 365/730 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FRMPD4 | c.2950G>T p.V984L | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GPR152 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 348/705 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HDGFL3 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 139/139 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPDL | c.465G>C p.L155F | Missense Mutation (SNP) | VAF 184/416 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCRS1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 151/425 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MKX | c.125A>T p.E42V | Missense Mutation (SNP) | VAF 442/1229 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MUC2 | c.825C>A p.C275* | Nonsense Mutation (SNP) | VAF 519/522 reads (99%) | called by muse, mutect2, varscan2
- NCKAP5 | c.4888G>C p.A1630P | Missense Mutation (SNP) | VAF 179/280 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ONECUT1 | c.635T>C p.M212T | Missense Mutation (SNP) | VAF 191/436 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- PCDHGB7 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 477/943 reads (51%) | called by muse, mutect2, varscan2
- PHKA1 | c.1289T>A p.F430Y | Missense Mutation (SNP) | VAF 276/503 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- PPP1R8 | c.888C>G p.N296K (on ENST00000311772 / NM_014110.5; = p.N72K on NM_002713.4) | Missense Mutation (SNP) | VAF 317/668 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RIN1 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 364/822 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.266); called by muse, varscan2
- SCN11A | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 171/172 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN3A | c.4253G>C p.G1418A | Missense Mutation (SNP) | VAF 77/568 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETBP1 | c.3644G>C p.S1215T | Missense Mutation (SNP) | VAF 226/500 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SIT1 | c.190T>A p.S64T | Missense Mutation (SNP) | VAF 159/756 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SORCS1 | c.1364T>A p.V455D | Missense Mutation (SNP) | VAF 118/397 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SOX2 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 120/2173 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2
- SPEG | c.9383T>A p.M3128K | Missense Mutation (SNP) | VAF 177/289 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- TENM2 | c.7474A>G p.N2492D (on ENST00000518659 / NM_001122679.2; = p.N2253D on NM_001080428.3) | Missense Mutation (SNP) | VAF 211/443 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TFPI | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM119 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 182/270 reads (67%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- UAP1 | c.1546G>C p.E516Q (on ENST00000271469 / NM_001324116.1; = p.E499Q on NM_003115.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/305 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDFY4 | c.7751C>A p.T2584K | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); called by muse, mutect2
- WDR7 | c.1043A>C p.D348A | Missense Mutation (SNP) | VAF 149/333 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- WDR92 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 210/297 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YIPF6 | c.309-1G>C p.X103_splice | Splice Site (SNP) | VAF 138/325 reads (42%) | called by muse, mutect2, varscan2
- ZNF335 | c.1917C>A p.H639Q | Missense Mutation (SNP) | VAF 209/422 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF417 | c.1623T>G p.I541M | Missense Mutation (SNP) | VAF 36/912 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- CATSPERE | c.1857G>A p.L619= | Silent (SNP) | VAF 203/731 reads (28%) | called by muse, mutect2, varscan2
- FAM83H | c.3195C>T p.T1065= | Silent (SNP) | VAF 528/1097 reads (48%) | called by muse, varscan2
- FMN2 | c.4365G>T p.L1455= | Silent (SNP) | VAF 186/681 reads (27%) | called by muse, mutect2
- GRIN2D | c.1932G>A p.S644= | Silent (SNP) | VAF 193/392 reads (49%) | catalogued as rs752875753; called by muse, mutect2, varscan2
- HBA1 | c.30C>T p.N10= | Silent (SNP) | VAF 87/682 reads (13%) | catalogued as rs28928885, CM024471; called by muse, mutect2, varscan2
- IL17RC | c.2049G>C p.S683= (on ENST00000295981 / NM_153461.4; = p.S597= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 385/788 reads (49%) | called by muse, mutect2, varscan2
- ILDR1 | c.249C>T p.S83= | Silent (SNP) | VAF 222/788 reads (28%) | catalogued as rs1211895480; called by muse, mutect2, varscan2
- KATNIP | c.3354G>A p.E1118= | Silent (SNP) | VAF 80/136 reads (59%) | called by muse, mutect2, varscan2
- KIF3B | c.297G>T p.G99= | Silent (SNP) | VAF 148/293 reads (51%) | called by muse, mutect2, varscan2
- OR2G2 | c.531G>A p.V177= | Silent (SNP) | VAF 97/682 reads (14%) | called by muse, mutect2, varscan2
- PAXIP1 | c.232C>T p.L78= | Silent (SNP) | VAF 97/385 reads (25%) | catalogued as COSV68186423; called by muse, mutect2, varscan2
- PRMT9 | c.1374T>A p.S458= | Silent (SNP) | VAF 159/160 reads (99%) | called by muse, mutect2, varscan2
- RIPPLY2 | c.123G>T p.V41= | Silent (SNP) | VAF 285/616 reads (46%) | called by muse, mutect2, varscan2
- RNF187 | c.525C>T p.Y175= | Silent (SNP) | VAF 238/451 reads (53%) | catalogued as COSV59960579; called by muse, mutect2, varscan2
- SPHK1 | c.192G>A p.V64= (on ENST00000392496 / NM_001355139.2; = p.V78= on NM_021972.4) | Silent (SNP) | VAF 661/662 reads (100%) | called by muse, mutect2, varscan2
- STUM | c.423G>T p.L141= | Silent (SNP) | VAF 471/473 reads (100%) | called by muse, mutect2, varscan2
- TBC1D2B | c.1254G>A p.E418= | Silent (SNP) | VAF 297/298 reads (100%) | called by muse, mutect2, varscan2
- TDRD15 | c.2391T>C p.S797= | Silent (SNP) | VAF 204/526 reads (39%) | catalogued as COSV101337856; called by muse, mutect2, varscan2
- ZNF71 | c.207G>T p.G69= | Silent (SNP) | VAF 300/939 reads (32%) | called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.-312G>T | 5'UTR (SNP) | VAF 537/1194 reads (45%) | called by muse, mutect2, varscan2
- PCMTD1 | c.-398G>T | 5'UTR (SNP) | VAF 259/611 reads (42%) | called by muse, mutect2, varscan2
